TCGA case TCGA-17-Z006 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University.
https://portal.gdc.cancer.gov/cases/53d7b0c2-b8ed-43c8-9ffd-a586e0a68086

Biospecimens (2 samples)
- Sample TCGA-17-Z006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TCGA-17-Z006-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
